HCMI case HCM-CSHL-0852-C76 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Other and ill-defined sites. Index date (day 0 for every day count below): sample procurement.
https://portal.gdc.cancer.gov/cases/a947e983-07c7-4bdf-9b3b-e6e72b6c41e5

Demographics
Sex at birth: male; Days to birth: -22,995 days (63.0 years before the index date); Year of birth: 1956; Vital status: Alive.

Diagnoses (2)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C76.0; Tissue or organ of origin: Head, face or neck, NOS; Classification of tumor: primary; AJCC staging edition: 8th; AJCC pathologic N: N1; Tumor grade: GX; Metastasis at diagnosis: Metastasis, NOS; Prior treatment: No; Sites of involvement: Lymph Node, Regional.
   Pathology details: Lymphatic invasion present: Yes; Tumor largest dimension diameter: 9.3 cm; Vascular invasion present: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Pharmaceutical Therapy, NOS, for residual disease.
2. Squamous cell carcinoma, metastatic, NOS: ICD-O-3 morphology code: 8070/6; ICD-10 code: C77.0; Tissue or organ of origin: Head, face or neck, NOS; Site of resection or biopsy: Lymph node, NOS; Classification of tumor: metastasis.

Follow-up (2 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence type: Regional; Progression or recurrence anatomic site: Lymph node, NOS; Days to progression: 0 days.
- Follow-up contact recording only the day: day 141.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 62 kg; Height: 180 cm; BMI: 19.1.

Family history
- Relationship type: First Degree Relative, NOS.

Biospecimens (2 samples)
- Sample HCM-CSHL-0852-C76-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen.
- Sample HCM-CSHL-0852-C76-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
